Somatic mutation profile of tumor specimen 0DU81A from CCDI case PBCKSZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,225 days).
Specimen 0DU81A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 452a257a-f328-49f3-9575-089aea213c1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU80C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a998e2fd-f18c-426f-a6e7-6568e52a806b

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCA | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 233/1245 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1555538571, CM050611, CM146018, COSV59796386; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 175/1153 reads (15%) | catalogued as rs779866340, COSV53982838, COSV99684621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBB3 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 262/1077 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs534724280; called by muse, mutect2, varscan2
- ELMO3 | c.1166G>A p.R389H (on ENST00000652269; = p.R336H on NM_024712.5) | Missense Mutation (SNP) | VAF 336/1385 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763179548; called by muse, mutect2, varscan2
- MOCS3 | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 280/1515 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs1204071186; called by mutect2, varscan2
- NPAS2 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 302/1951 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376677213; called by muse, mutect2, varscan2
- NRXN3 | c.3158G>C p.C1053S (on ENST00000335750 / NM_001330195.2; = p.C680S on NM_004796.6) | Missense Mutation (SNP) | VAF 249/1414 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59761206, COSV59786394; called by muse, mutect2, varscan2
- PGLYRP4 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 259/1159 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs1479813549, COSV100668549; called by muse, mutect2, varscan2
- SH3RF2 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 203/1429 reads (14%) | catalogued as rs760574672; called by muse, mutect2, varscan2
- C18orf63 | c.1145dup p.S383Lfs*13 | Frame Shift Ins (INS) | VAF 162/1183 reads (14%) | called by mutect2, varscan2
- CPSF7 | c.317G>A p.G106E (on ENST00000394888 / NM_001136040.4; = p.G149E on NM_024811.4) | Missense Mutation (SNP) | VAF 526/1737 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- GBP1 | c.938A>G p.E313G | Missense Mutation (SNP) | VAF 41/1257 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRC63 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 179/676 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OR5AN1 | c.298A>T p.I100F | Missense Mutation (SNP) | VAF 116/337 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SH3D19 | c.1922C>T p.T641I | Missense Mutation (SNP) | VAF 288/1852 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SPAM1 | c.24C>A p.H8Q | Missense Mutation (SNP) | VAF 203/2022 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- TCOF1 | c.2770G>T p.A924S (on ENST00000377797 / NM_001135243.1; = p.A847S on NM_000356.4) | Missense Mutation (SNP) | VAF 193/1631 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZNF777 | c.1543del p.R515Gfs*12 | Frame Shift Del (DEL) | VAF 118/1005 reads (12%) | called by mutect2, varscan2
- ZSCAN5A | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 252/1410 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- GPR50 | c.312C>T p.V104= | Silent (SNP) | VAF 1219/1278 reads (95%) | catalogued as rs748715543, COSV54441449; called by muse, mutect2, varscan2
- PLEKHG5 | c.936C>A p.G312= (on ENST00000400915 / NM_001042663.3; = p.G275= on NM_020631.6) | Silent (SNP) | VAF 302/1430 reads (21%) | called by mutect2, varscan2
- PLEKHO1 | c.1173G>A p.P391= | Silent (SNP) | VAF 235/1186 reads (20%) | catalogued as rs782011779; called by muse, mutect2, varscan2
- ALPK1 | c.277-23G>A | Intron (SNP) | VAF 58/239 reads (24%) | catalogued as rs928436331; called by muse, mutect2, varscan2
- KITLG | c.-37C>T | 5'UTR (SNP) | VAF 176/875 reads (20%) | catalogued as rs1258980785; called by muse, mutect2, varscan2
- PLA2G6 | c.426-98C>A | Intron (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
